Somatic mutation profile of tumor specimen TCGA-VD-AA8T-01A (aliquot TCGA-VD-AA8T-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8T, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIA; Age at diagnosis: 83.4 years (30,475 days).
Specimen TCGA-VD-AA8T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90629ed4-8b75-4895-aa1f-302281184b1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8T-10A (Blood Derived Normal), aliquot TCGA-VD-AA8T-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e5c725c-68ac-47c5-8a25-33f1c0dd8a45

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FCGRT | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs778656931; called by muse, mutect2, varscan2
- RRBP1 | c.1858A>G p.K620E (on ENST00000377813 / NM_001365613.2; = p.K190E on NM_004587.3) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs758259417; called by muse, mutect2, varscan2
- BAP1 | c.1491dup p.E498* | Frame Shift Ins (INS) | VAF 10/11 reads (91%) | called by mutect2, varscan2
- DOP1A | c.6794C>T p.S2265L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GALT | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2
- IL24 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- MYH11 | c.4627_4629del p.E1543del | In Frame Del (DEL) | VAF 22/83 reads (27%) | called by pindel, varscan2
- PAXBP1 | c.2139del p.K713Nfs*2 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | called by mutect2, pindel, varscan2
- PPP2R2A | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPCN1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM21 | c.1668T>C p.S556= | Silent (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- GRM6 | c.2292G>A p.T764= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs781607214; called by muse, mutect2, varscan2
- HELZ2 | c.6480G>A p.A2160= (on ENST00000467148 / NM_001037335.2; = p.A1591= on NM_033405.3) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs949392781; called by muse, mutect2
- JAML | c.786G>A p.P262= (on ENST00000356289 / NM_001098526.2; = p.P252= on NM_153206.3) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs377621403; called by muse, mutect2, varscan2
- ZNF836 | c.1680C>G p.G560= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
